Gene-level copy-number profile of tumor specimen TARGET-10-PASKGG-09A from TARGET case TARGET-10-PASKGG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.6 years (5,682 days).
Specimen TARGET-10-PASKGG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d8a24003-f2f6-5f00-b001-4a7adf9ac2c5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASKGG-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate.
https://portal.gdc.cancer.gov/files/ac2bcecc-a37c-43b6-a332-f1cca1c75ee6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 3,249; copy number 2: 56,585; copy number 3: 224; copy number 4: 4; copy number 5: 80.

Homozygous deletions (total copy number 0; autosomes only): 122 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,170,011–127,170,231, 1 gene: NIFKP9.
- chr7:38,256,337–38,292,078, 6 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11.
- chr7:142,580,917–142,786,224, 27 genes: TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes (within-gene range 0–2): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr14:22,123,318–22,530,378, 79 genes (broad region; genes not listed).
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–89,969,335, 68 genes, copy number 5 (broad region; genes not listed).
- chr15:25,062,333–25,081,378, 11 genes, copy number 5: SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.

Autosomal genes at a single copy (total copy number 1): 861. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
